Gene-level copy-number profile of tumor specimen HTMCP-02-15-01090-01A from CGCI case HTMCP-02-15-01090, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Large cell neuroendocrine carcinoma; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 61.1 years (22,307 days).
Specimen HTMCP-02-15-01090-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1251f497-4042-420e-bfa9-3d79555eca92.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-15-01090-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,242 have no estimate.
https://portal.gdc.cancer.gov/files/423bbc75-8ec1-4eb2-b9e4-b54235a024bc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 52; copy number 1: 12,326; copy number 2: 40,480; copy number 3: 5,339; copy number 4: 126; copy number 5: 18; copy number 6: 16; copy number 7: 2; copy number 8: 19; copy number 47: 3.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–133,723, 11 genes (within-gene range 0–1): DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3.
- chr3:46,712,115–46,812,574, 8 genes (within-gene range 0–1): AC109583.1, PRSS50, PRSS46P, PRSS45P, AC109583.4, PRSS43P, AC109583.2, PRSS44P.
- chr3:72,888,046–73,241,896, 10 genes: GXYLT2, Metazoa_SRP, FTH1P23, PPP4R2, RNU7-19P, EBLN2, RNU6-557P, RNU2-64P, CCDC75P1, RNU6-1270P.
- chr6:162,568,379–162,569,728, 1 gene (within-gene range 0–1): KRT8P44.
- chr8:7,495,911–7,509,311, 1 gene: DEFB107B.
- chr8:12,628,476–12,638,602, 2 genes: RPS3AP35, AC068587.3.
- chr9:61,190,003–61,582,675, 8 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3.
- chr19:1,815,248–1,863,579, 7 genes (within-gene range 0–2): REXO1, AC012615.2, MIR1909, AC012615.6, AC012615.3, KLF16, AC012615.4.
- chr19:43,192,702–43,269,530, 3 genes: PSG4, CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 58 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,450,245, 3 genes, copy number 5: AC239859.5, RNA5SP533, AC239859.3.
- chr1:143,784,376–143,797,108, 3 genes, copy number 47: AC239800.3, LINC02591, RNU1-143P.
- chr6:70,663,502–71,652,611, 23 genes, copy number 5–8: SLC25A6P6, SMAP1, AL354943.1, NDUFAB1P1, B3GAT2, BECN1P2, U3, LYPLA1P3, RNU6-411P, AL589935.1, AL589935.3, AL589935.2, OGFRL1, AL136164.2, AL136164.1, LINC00472, MIR30C2, AL136164.3, MIR30A, LINC01626, AL035467.1, KRT19P1, RNU4-66P.
- chr7:32,951,426–33,006,930, 3 genes, copy number 5: AC083863.1, FKBP9, RNU6-388P.
- chr7:38,239,580–38,249,572, 1 gene, copy number 6: TRGC2.
- chr7:38,257,879–38,340,998, 14 genes, copy number 6: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr15:21,293,653–21,295,201, 1 gene, copy number 5: AC068446.1.
- chr15:21,980,277–22,083,221, 7 genes, copy number 5–6 (within-gene range 2–9): OR11J6P, AC134980.1, OR11H3P, OR11K1P, OR4Q1P, OR4H6P, OR4M2.
- chr15:22,160,431–22,185,402, 3 genes, copy number 7–8: IGHV1OR15-1, IGHV1OR15-3, IGHV4OR15-8.

Autosomal genes at a single copy (total copy number 1): 10,903. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
